Somatic mutation profile of tumor specimen MP2PRT-PAUSXF-TMP1-A (aliquot MP2PRT-PAUSXF-TMP1-A-1-0-D-A81Z-36) from MP2PRT case MP2PRT-PAUSXF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.5 years (901 days).
Specimen MP2PRT-PAUSXF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9de3400a-55cd-4c25-a790-d78e20c1815a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUSXF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUSXF-NB1-A-1-0-D-A81Z-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ab48f6f-286c-429e-8147-b51e5c815586

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 6, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CBLC | c.899A>T p.E300V | Missense Mutation (SNP) | VAF 106/356 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.29); catalogued as COSV54322873; called by muse, mutect2, varscan2
- PROX1 | c.1330C>T p.R444C | Missense Mutation (SNP) | VAF 130/603 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765247780, COSV54784534; called by muse, mutect2, varscan2
- E2F8 | c.605A>G p.Y202C | Missense Mutation (SNP) | VAF 155/476 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FOXN4 | c.1343T>C p.L448P | Missense Mutation (SNP) | VAF 98/411 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCSK6 | c.2743T>C p.C915R | Missense Mutation (SNP) | VAF 103/368 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- TAF2 | c.22C>A p.P8T | Missense Mutation (SNP) | VAF 101/407 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CTSC | c.1182A>G p.R394= | Silent (SNP) | VAF 32/446 reads (7%) | called by muse, mutect2
- LRRN2 | c.114G>T p.R38= | Silent (SNP) | VAF 122/577 reads (21%) | called by muse, mutect2, varscan2
- MUC16 | c.19824G>A p.S6608= | Silent (SNP) | VAF 64/277 reads (23%) | catalogued as rs558114930; called by muse, mutect2, varscan2
- SCUBE1 | c.1152C>T p.Y384= | Silent (SNP) | VAF 65/389 reads (17%) | catalogued as rs368075176, COSV100683456; called by muse, mutect2, varscan2
